Somatic mutation profile of cancer-model specimen HCM-BROD-0411-C25-85M (3D Organoid, passage 10; aliquot HCM-BROD-0411-C25-85M-01D-A78T-36), derived from the metastatic tumor of HCMI case HCM-BROD-0411-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 81.7 years (29,843 days).
Specimen HCM-BROD-0411-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dad3fcf6-7b0c-4890-bba9-6ab24b05d68e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0411-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0411-C25-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9264d6f4-5593-4e08-b179-e31544617fe2

The open-access MAF lists 84 somatic variants for this specimen: 57 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 23, Nonsense Mutation 4, RNA 3, Frame Shift Del 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 350/414 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.3716C>T p.T1239M | Missense Mutation (SNP) | VAF 121/178 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs377367890, COSV66307307; called by muse, mutect2, varscan2
- ADGRB1 | c.4172G>A p.R1391H | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs765352565; called by muse, mutect2
- ALG9 | c.1711A>G p.R571G (on ENST00000614444 / NM_001352418.1; = p.R578G on NM_024740.2) | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs1555089112; called by muse, mutect2, varscan2
- ARID1A | c.1653C>G p.Y551* | Nonsense Mutation (SNP) | VAF 273/464 reads (59%) | catalogued as rs1553149467, COSV61379405; ClinVar: association; called by muse, mutect2, varscan2
- BMPR1B | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs377000102, COSV52777569, COSV52777734; called by muse, mutect2, varscan2
- CDH22 | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV64838979; called by muse, mutect2, varscan2
- DRD3 | c.754C>G p.L252V | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs1181229994; called by muse, varscan2
- DSE | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 43/76 reads (57%) | catalogued as rs759461496; called by muse, mutect2, varscan2
- EPHA4 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1255538022, COSV56033626; called by muse, mutect2, varscan2
- EPN2 | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768345994; called by muse, mutect2, varscan2
- HEYL | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 86/303 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs139668981; called by muse, mutect2, varscan2
- HMCN1 | c.8603C>T p.P2868L | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1177935297; called by muse, mutect2, varscan2
- IGFN1 | c.1957G>T p.V653F (on ENST00000295591 / NM_001367841.1; = p.V3110F on NM_001164586.2) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs747091077; called by muse, mutect2, varscan2
- KIF26A | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 112/346 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1377746570; called by muse, mutect2, varscan2
- LAMA1 | c.5413C>A p.L1805M | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); catalogued as COSV67541068; called by muse, mutect2
- OR1M1 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 276/276 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs145395343; called by muse, mutect2, varscan2
- OR4A16 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.071); catalogued as COSV59043889; called by muse, mutect2, varscan2
- PCP4 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs748762723, COSV60788692; called by muse, mutect2, varscan2
- PDE11A | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 98/202 reads (49%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.845); catalogued as rs751602560, COSV53693551; called by muse, varscan2
- PLG | c.1987C>T p.R663* | Nonsense Mutation (SNP) | VAF 41/133 reads (31%) | catalogued as rs752522150, CM154959, COSV57513850; called by muse, mutect2, varscan2
- PPP1R3A | c.1456C>T p.R486* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as rs780306610, COSV52882236; called by muse, mutect2, varscan2
- PTGIS | c.116G>T p.W39L | Missense Mutation (SNP) | VAF 308/471 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs911460406; called by muse, mutect2, varscan2
- SLC32A1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV99462562; called by muse, mutect2, varscan2
- SLC34A1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 352/525 reads (67%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs1457641719; called by muse, mutect2, varscan2
- TP53 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 181/183 reads (99%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs750600586, CM123559, COSV52661339, COSV52708439, COSV53502932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | PolyPhen benign (0.117); catalogued as COSV100589825, COSV60018397; called by muse, mutect2, varscan2
- USP6 | c.3112C>T p.R1038C | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as rs765594911, COSV51479257; called by muse, mutect2, varscan2
- ABCA12 | c.5300T>A p.L1767Q (on ENST00000272895 / NM_173076.3; = p.L1449Q on NM_015657.3) | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRD2 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 53/53 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AKAP13 | c.1537A>G p.I513V | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASPM | c.4322C>T p.S1441L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASS4 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 222/291 reads (76%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPYSL3 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 49/392 reads (13%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EIF4EBP1 | c.125T>G p.L42R | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAF2 | c.1148_1155+2del | Frame Shift Del (DEL) | VAF 25/45 reads (56%) | called by mutect2, pindel, varscan2
- FER | c.1463A>T p.K488I | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRM3 | c.1807A>C p.N603H | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HACD1 | c.513dup p.L172Sfs*21 | Frame Shift Ins (INS) | VAF 28/72 reads (39%) | called by mutect2, pindel, varscan2
- KCNC2 | c.1140T>G p.N380K | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.475); called by muse, mutect2
- LILRA6 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 200/262 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- MS4A14 | c.787_788del p.M263Vfs*9 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | called by pindel, varscan2
- MUC17 | c.6647G>C p.S2216T | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- MYLK | c.2402G>C p.G801A | Missense Mutation (SNP) | VAF 46/383 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NCAM2 | c.385G>C p.G129R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCAPD3 | c.1699A>G p.S567G | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NSD3 | c.3919C>G p.Q1307E | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAP1GDS1 | c.548C>G p.P183R (on ENST00000408927 / NM_001100427.2; = p.P184R on NM_021159.5) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- RIMS2 | c.2105A>C p.Q702P (on ENST00000666250 / NM_001348490.2; = p.Q510P on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIPOR1 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SDK2 | c.3815A>G p.Y1272C | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHANK1 | c.3583G>A p.G1195S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.82); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLC7A1 | c.1403T>G p.F468C | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- SPTBN5 | c.9554C>A p.A3185D | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- TGFBR2 | c.398T>C p.F133S | Missense Mutation (SNP) | VAF 100/100 reads (100%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TRIML1 | c.605A>T p.Q202L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- TRPV6 | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 79/425 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADAMTS14 | c.1359C>T p.Y453= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as rs367637583, COSV64599894; called by muse, mutect2, varscan2
- ADD2 | c.1626C>T p.D542= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as rs782116985, COSV52462765; called by muse, mutect2, varscan2
- ARFGEF1 | c.1776A>T p.G592= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- ATP2C1 | c.2610T>G p.T870= | Silent (SNP) | VAF 60/60 reads (100%) | called by muse, mutect2, varscan2
- BASP1 | c.183C>T p.D61= | Silent (SNP) | VAF 78/117 reads (67%) | catalogued as rs1029579368, COSV59472653; called by muse, mutect2, varscan2
- CASP8AP2 | c.5049C>T p.Y1683= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs545122264, COSV99386690; called by muse, mutect2, varscan2
- CDH22 | c.162G>A p.A54= | Silent (SNP) | VAF 287/415 reads (69%) | called by muse, mutect2, varscan2
- CFC1 | c.240C>T p.F80= | Silent (SNP) | VAF 188/841 reads (22%) | catalogued as rs762056382, COSV52090345, COSV52090471; called by muse, mutect2, varscan2
- CNTNAP2 | c.3360C>T p.H1120= | Silent (SNP) | VAF 72/162 reads (44%) | catalogued as rs563414260, COSV62149566; ClinVar: likely benign; called by muse, mutect2, varscan2
- EFNA2 | c.36G>A p.L12= | Silent (SNP) | VAF 134/134 reads (100%) | catalogued as rs974949419; called by muse, mutect2, varscan2
- FAM47B | c.90C>T p.F30= | Silent (SNP) | VAF 44/47 reads (94%) | catalogued as COSV61456092, COSV61456316; called by muse, mutect2, varscan2
- GABRA3 | c.381G>A p.L127= | Silent (SNP) | VAF 79/140 reads (56%) | called by muse, mutect2, varscan2
- HSPG2 | c.5085C>A p.S1695= | Silent (SNP) | VAF 40/250 reads (16%) | catalogued as COSV101021359; called by muse, mutect2, varscan2
- KCNQ3 | c.150G>T p.V50= | Silent (SNP) | VAF 68/247 reads (28%) | called by muse, mutect2, varscan2
- L1TD1 | c.2187T>C p.F729= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1186354771; called by muse, mutect2, varscan2
- MYH4 | c.3388C>A p.R1130= | Silent (SNP) | VAF 237/242 reads (98%) | catalogued as rs772548795; called by muse, mutect2, varscan2
- NTSR1 | c.939G>C p.V313= | Silent (SNP) | VAF 63/536 reads (12%) | called by muse, mutect2, varscan2
- PNPLA3 | c.465C>T p.I155= | Silent (SNP) | VAF 69/186 reads (37%) | called by mutect2, varscan2
- POM121 | c.3336G>A p.G1112= (on ENST00000434423; = p.G847= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 80/319 reads (25%) | catalogued as COSV57521283; called by muse, mutect2, varscan2
- POU4F2 | c.1029G>A p.A343= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs370767940, COSV99850807; called by muse, mutect2, varscan2
- RASSF2 | c.498C>T p.R166= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs773845628; called by muse, mutect2, varscan2
- RGPD3 | c.60G>A p.P20= | Silent (SNP) | VAF 282/681 reads (41%) | catalogued as rs778699719; called by muse, mutect2, varscan2
- SORCS3 | c.2037C>T p.S679= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs773731511, COSV63797240; called by muse, mutect2, varscan2
- AC091304.1 | n.398A>G | RNA (SNP) | VAF 16/612 reads (3%) | called by muse, mutect2
- C5orf64 | n.512+8395C>A | Intron (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2, varscan2
- FOLH1B | n.1383del | RNA (DEL) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- SNORD115-25 | n.10A>G | RNA (SNP) | VAF 28/215 reads (13%) | called by muse, mutect2, varscan2
